Somatic mutation profile of tumor specimen TCGA-CF-A9FL-01A (aliquot TCGA-CF-A9FL-01A-11D-A38G-08) from TCGA case TCGA-CF-A9FL, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 85.1 years (31,099 days).
Specimen TCGA-CF-A9FL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3b61483-54f6-4fed-b973-36595f023e56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A9FL-10A (Blood Derived Normal), aliquot TCGA-CF-A9FL-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/356d0a9e-7612-42b9-af74-aa6661e2d282

The open-access MAF lists 62 somatic variants for this specimen: 46 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 15, Frame Shift Del 7, Nonsense Mutation 3, In Frame Del 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.1205T>C p.I402T | Missense Mutation (SNP) | VAF 224/270 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV64881908, COSV64883711; called by muse, mutect2, varscan2
- BEND3 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781987529, COSV64682340; called by muse, mutect2, varscan2
- BTRC | c.1638_1639del p.C547Sfs*17 (on ENST00000370187 / NM_033637.4; = p.C511Sfs*17 on NM_003939.5) | Frame Shift Del (DEL) | VAF 40/131 reads (31%) | catalogued as rs745797916; called by pindel, varscan2
- CEP41 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs976909451, COSV56221504; called by muse, mutect2, varscan2
- CMTR2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as rs960907780, COSV57605066; called by muse, mutect2, varscan2
- CPSF3 | c.1004G>C p.G335A | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53011975; called by muse, mutect2, varscan2
- CREBBP | c.1864_1885del p.K622Wfs*2 | Frame Shift Del (DEL) | VAF 39/156 reads (25%) | catalogued as COSV52141455; called by mutect2, pindel, varscan2
- DAXX | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV56472790; called by muse, mutect2, varscan2
- DCLK1 | c.80T>G p.V27G | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55211890; called by muse, varscan2
- EFEMP1 | c.143G>T p.C48F | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62617937; called by muse, mutect2, varscan2
- ELF3 | c.1055A>G p.Y352C | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62840471; called by muse, mutect2, varscan2
- ERGIC2 | c.564del p.V189Wfs*29 | Frame Shift Del (DEL) | VAF 32/95 reads (34%) | catalogued as COSV64113456; called by mutect2, pindel*, varscan2
- EXTL3 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs375285295; called by muse, mutect2, varscan2
- FAM189B | c.1852G>T p.G618C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs1230360083, COSV59171076; called by muse, mutect2, varscan2
- HIP1R | c.2639G>A p.G880D | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53444967; called by muse, mutect2
- HMCN1 | c.8224C>T p.R2742* | Nonsense Mutation (SNP) | VAF 40/91 reads (44%) | catalogued as rs1030679583, COSV54908664; called by muse, mutect2, varscan2
- HNRNPH1 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV61485846, COSV61488433; called by muse, mutect2, varscan2
- IGDCC3 | c.2272G>A p.G758S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763080497, COSV60078564; called by muse, mutect2
- INPP5F | c.1538G>T p.S513I | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62823878; called by muse, mutect2, varscan2
- IQGAP1 | c.2893_2894del p.K965Efs*62 | Frame Shift Del (DEL) | VAF 45/144 reads (31%) | catalogued as COSV51591476; called by mutect2, pindel, varscan2
- KLF8 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV63847418, COSV63848920; called by muse, mutect2, varscan2
- KMT2D | c.4579G>T p.E1527* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV56497114, COSV99979789; called by muse, mutect2, varscan2
- LTBP4 | c.2933G>A p.C978Y (on ENST00000308370 / NM_001042544.1; = p.C941Y on NM_003573.2) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766287114, COSV52590917, COSV99198996; called by muse, mutect2, varscan2
- MIIP | c.330A>T p.R110S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV52428851; called by muse, varscan2
- OPRK1 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs201685919, COSV55569660; called by muse, mutect2, varscan2
- PAM | c.2771G>A p.G924D (on ENST00000438793 / NM_001319943.1; = p.G925D on NM_000919.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57220213; called by muse, mutect2, varscan2
- PCNT | c.8623T>A p.L2875I | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs1488731530, COSV64033159; called by muse, mutect2
- PER1 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1282783693, COSV57918290; called by muse, mutect2
- POM121L12 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs372490884, COSV68692951, COSV68693360; called by muse, mutect2, varscan2
- PPOX | c.713A>C p.Q238P | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV57091303; called by muse, mutect2, varscan2
- PPP1R3A | c.1210C>A p.P404T | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV52893405; called by muse, mutect2, varscan2
- PPP3CA | c.1339G>C p.A447P | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100547524, COSV59931746; called by muse, mutect2, varscan2
- PREX2 | c.2285A>G p.E762G | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55799166; called by muse, mutect2, varscan2
- PXK | c.1375dup p.R459Kfs*15 | Frame Shift Ins (INS) | VAF 14/36 reads (39%) | catalogued as rs751548577; called by mutect2, varscan2
- RIOK3 | c.310A>G p.N104D | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1415574167, COSV59775186; called by muse, mutect2, varscan2
- RYR2 | c.1496T>C p.L499P | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV63714522; called by muse, mutect2, varscan2
- SEMA3B | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs782766477, COSV100312875; called by muse, mutect2, varscan2
- THNSL1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765878202, COSV64479792; called by muse, mutect2, varscan2
- THNSL2 | c.356G>T p.C119F | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.288); catalogued as COSV59084829; called by muse, mutect2, varscan2
- TYK2 | c.1607G>T p.C536F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.042); catalogued as COSV53392112; called by muse, mutect2, varscan2
- ZNF770 | c.1085A>C p.K362T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs1412369317, COSV62545104; called by muse, mutect2, varscan2
- B3GALT2 | c.226_228del p.H76del | In Frame Del (DEL) | VAF 91/159 reads (57%) | called by mutect2, pindel, varscan2
- CMTR2 | c.720_737del p.C240_E246delins* | Nonsense Mutation (DEL) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- KMT2C | c.14592_14593del p.G4865Tfs*20 | Frame Shift Del (DEL) | VAF 48/176 reads (27%) | called by pindel, varscan2
- RCOR3 | c.931_946del p.A311Lfs*9 | Frame Shift Del (DEL) | VAF 24/127 reads (19%) | called by mutect2, pindel, varscan2
- RSPH1 | c.500del p.N167Ifs*22 | Frame Shift Del (DEL) | VAF 21/106 reads (20%) | called by mutect2, pindel, varscan2
- ACTR5 | c.537G>T p.S179= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV54762251; called by muse, mutect2, varscan2
- BPIFB4 | c.1377A>T p.T459= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as COSV64950901, COSV64952399; called by muse, mutect2
- CDON | c.3471G>A p.V1157= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV55002681; called by muse, mutect2, varscan2
- CEBPA | c.984G>A p.V328= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV57199897; called by muse, mutect2, varscan2
- CLIP4 | c.1011C>T p.A337= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV60752866; called by muse, mutect2, varscan2
- DNAJC13 | c.1722C>A p.S574= | Silent (SNP) | VAF 60/143 reads (42%) | catalogued as rs1421924862, COSV53458455; called by muse, mutect2, varscan2
- FUT9 | c.546G>A p.V182= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV56157277; called by muse, mutect2, varscan2
- GRIA1 | c.378C>T p.R126= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs1237957759, COSV53625138; called by muse, mutect2, varscan2
- GSTT2 | c.168G>T p.T56= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV53160194, COSV53160435; called by muse, mutect2, varscan2
- JPH1 | c.495G>A p.S165= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as COSV60614865; called by muse, mutect2, varscan2
- MYO18A | c.3807G>A p.K1269= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV62873550; called by muse, mutect2, varscan2
- TNC | c.5700G>A p.S1900= | Silent (SNP) | VAF 32/46 reads (70%) | catalogued as rs150811111; called by muse, mutect2, varscan2
- TOGARAM1 | c.522G>A p.E174= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV61889413; called by muse, mutect2, varscan2
- TTN | c.79059G>T p.V26353= (on ENST00000591111; = p.V18929= on NM_003319.4) | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs1264771090, COSV60355915; called by muse, mutect2, varscan2
- XIRP1 | c.4809C>T p.V1603= | Silent (SNP) | VAF 65/175 reads (37%) | catalogued as rs781450401, COSV61141442; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500396 C>T | 5'Flank (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
